Somatic mutation profile of tumor specimen CDDP-ACJ1-TTP1-A (aliquot CDDP-ACJ1-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACJ1, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79 years.
Specimen CDDP-ACJ1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94620bf8-ecf8-428c-9b53-2b84813938cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACJ1-NB1-A (Blood Derived Normal), aliquot CDDP-ACJ1-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48cece40-f5f9-4417-a4ae-c94e84d356dd

The open-access MAF lists 588 somatic variants for this specimen: 383 protein-altering or splice-affecting, 125 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 125, Nonsense Mutation 50, Intron 31, 5'UTR 17, 3'UTR 12, RNA 9, 5'Flank 8, Splice Region 7, Splice Site 4, Frame Shift Del 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 134/615 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PROC | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 82/611 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121918160, CM951016, COSV52167582; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs1331999813; called by muse, mutect2
- ACAN | c.6856G>T p.E2286* | Nonsense Mutation (SNP) | VAF 17/195 reads (9%) | catalogued as COSV100717474; called by muse, mutect2
- ADAMTSL4 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs770157227; called by muse, mutect2
- ADCY10 | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 28/613 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63242786; called by muse, mutect2
- AMIGO2 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 57/447 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV56973864; called by muse, mutect2, varscan2
- AMZ1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 42/577 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56687076; called by muse, mutect2
- ANAPC5 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 38/458 reads (8%) | catalogued as rs782122962, COSV55841738; called by muse, mutect2
- ANGPT1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 58/528 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV52456678; called by muse, mutect2, varscan2
- APOB | c.10563G>C p.L3521F | Missense Mutation (SNP) | VAF 27/301 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV51935851; called by muse, mutect2
- ATRX | c.6867C>G p.F2289L | Missense Mutation (SNP) | VAF 64/838 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV64876920; called by muse, mutect2
- BAZ2B | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs777051221; called by muse, mutect2, varscan2
- BHLHE40 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 50/716 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV56576180; called by muse, mutect2
- BLOC1S3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1163081079; called by muse, mutect2
- C16orf46 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV100215524; called by muse, mutect2
- C6 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 76/784 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); catalogued as COSV99667607; called by muse, mutect2
- CAMSAP1 | c.2571G>C p.Q857H | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); catalogued as COSV100409966; called by muse, mutect2
- CASQ2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 53/542 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1345283398, COSV54773406; called by muse, mutect2, varscan2
- CAVIN3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58269136, COSV58269396; called by muse, mutect2
- CDK9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 90/1206 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100953723; called by muse, mutect2
- CDYL2 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 43/693 reads (6%) | catalogued as COSV73647563; called by muse, mutect2
- CELSR1 | c.3381C>G p.I1127M | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1459742035, COSV53091171; called by muse, mutect2
- CFAP61 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99847086; called by muse, mutect2, varscan2
- CHL1 | c.3619C>T p.R1207W (on ENST00000397491 / NM_001253387.1; = p.R1223W on NM_006614.4) | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs866660471, COSV56586680; called by muse, mutect2
- CLUL1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.682); catalogued as COSV58111629; called by muse, mutect2
- CNOT2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs1215721709; called by muse, mutect2
- COL4A3 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs1158524505; called by muse, mutect2
- COPS6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 46/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57994444; called by muse, mutect2
- COPS7A | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs1316426804; called by muse, mutect2, varscan2
- COQ5 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 54/1430 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs984958907; called by muse, mutect2
- CPNE6 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV53744248, COSV53745768; called by muse, mutect2
- CREBBP | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 20/306 reads (7%) | catalogued as COSV52135898; called by muse, mutect2
- CTR9 | c.2805G>T p.K935N | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as COSV100797334, COSV100797409; called by muse, mutect2
- CTTNBP2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 78/601 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1266580838; called by muse, mutect2, varscan2
- DDX39B | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 52/767 reads (7%) | catalogued as COSV66019554; called by muse, mutect2
- DHX37 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV58135068; called by muse, mutect2
- DNAH12 | c.7972G>C p.E2658Q (on ENST00000351747; = p.E3526Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99049235; called by muse, mutect2
- DNAJC22 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV67711769; called by muse, mutect2
- DPP7 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 49/616 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1438310633; called by muse, mutect2
- DSEL | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59492721; called by muse, mutect2
- DYNC1H1 | c.8659G>A p.E2887K | Missense Mutation (SNP) | VAF 31/451 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV64143217; called by muse, mutect2
- EML1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 37/442 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV51750940; called by muse, mutect2
- EPPK1 | c.4617C>G p.I1539M | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs781892821; called by muse, mutect2
- EPPK1 | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV101599745; called by muse, mutect2, varscan2
- ERF | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.087); catalogued as rs745819984, COSV55897355; called by muse, mutect2
- EYS | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 63/521 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs1262791683; called by muse, mutect2, varscan2
- FAM47A | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as rs780521265, COSV60495193, COSV60498365, COSV60499348; called by muse, mutect2, varscan2
- FAM50A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs782158952; called by muse, mutect2
- G6PD | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100855113; called by muse, mutect2
- GET1-SH3BGR | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61323282; called by muse, mutect2
- GLI4 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs778853001; called by muse, mutect2, varscan2
- GMPR | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148940073; called by muse, mutect2
- HAL | c.1598C>G p.S533C | Missense Mutation (SNP) | VAF 28/788 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54120337; called by muse, mutect2
- HSPH1 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60712766; called by muse, mutect2
- IMPA1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 90/756 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs1399459437; called by muse, mutect2, varscan2
- ITGAD | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV101210377; called by muse, mutect2, varscan2
- JAG1 | c.2960A>G p.N987S | Missense Mutation (SNP) | VAF 125/718 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as CD003530, CD030150; called by muse, mutect2, varscan2
- KRTAP10-11 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 52/616 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as rs782532520; called by muse, mutect2
- L1TD1 | c.1065G>C p.L355F | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63134199; called by muse, mutect2
- LILRB5 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.729); catalogued as COSV60256356, COSV60260489; called by muse, varscan2
- LRFN3 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.91); catalogued as rs1232454266; called by muse, mutect2
- LRGUK | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as rs201330287; called by muse, mutect2
- LRRC40 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 29/455 reads (6%) | catalogued as COSV100918685; called by muse, mutect2
- LRTM2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs527284344, COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- MCM7 | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV57993829; called by muse, mutect2
- MED12 | c.2121G>C p.E707D | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV100379896; called by muse, mutect2
- MMP14 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 55/687 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs756678996, COSV61287270; called by muse, mutect2
- MSTN | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 89/638 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs753241714, COSV53620696; called by muse, mutect2, varscan2
- MTMR4 | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs1259726445, COSV60204613; called by muse, mutect2, varscan2
- MXRA5 | c.1140G>C p.L380F | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54223836; called by muse, mutect2, varscan2
- MYO10 | c.4042G>A p.D1348N | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV57016726; called by muse, mutect2
- MYO15B | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs915495789; called by muse, mutect2
- MYO5A | c.3906G>C p.M1302I | Missense Mutation (SNP) | VAF 60/643 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV62556195; called by muse, mutect2
- NCAM2 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as COSV53066927, COSV53094159; called by muse, mutect2
- NEK4 | c.2166G>C p.E722D | Missense Mutation (SNP) | VAF 40/587 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV104431925; called by muse, mutect2
- NEK6 | c.297A>G p.Q99= | Splice Region (SNP) | VAF 20/186 reads (11%) | catalogued as rs138847171; called by muse, varscan2
- NF1 | c.4360C>G p.L1454V (on ENST00000358273 / NM_001042492.3; = p.L1433V on NM_000267.3) | Missense Mutation (SNP) | VAF 62/638 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.053); catalogued as rs1408832954; ClinVar: uncertain significance; called by muse, mutect2
- NOX1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54194335, COSV54195881; called by muse, mutect2, varscan2
- OR52H1 | c.510C>G p.F170L (on ENST00000322653; = p.F176L on NM_001005289.1) | Missense Mutation (SNP) | VAF 44/592 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59504733, COSV59505417; called by muse, mutect2
- OR5AN1 | c.453G>C p.M151I | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.119); catalogued as rs1358175643; called by muse, mutect2, varscan2
- ORC4 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51572755, COSV51577173; called by muse, mutect2
- PCDH15 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1482395629, COSV100217268; called by muse, mutect2
- PCDHA1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as COSV65376031; called by muse, mutect2
- PCDHA4 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 71/532 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); catalogued as rs781794809; called by muse, mutect2, varscan2
- PCDHA8 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV65334095; called by muse, mutect2, varscan2
- PDE1B | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54494902; called by muse, mutect2
- PDGFRA | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57265922; called by muse, mutect2
- PEX11G | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs758752163, COSV55537577, COSV99078147; called by muse, mutect2, varscan2
- PHLPP1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.01); catalogued as COSV53040197; called by muse, mutect2
- PIKFYVE | c.3101C>G p.S1034C | Missense Mutation (SNP) | VAF 69/700 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV52238185; called by muse, mutect2
- PKHD1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 118/678 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61893421; called by muse, mutect2, varscan2
- PKP4 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61578774; called by muse, mutect2
- PLCB1 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 107/601 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62068983; called by muse, mutect2, varscan2
- PMS2 | c.164-1G>T p.X55_splice | Splice Site (SNP) | VAF 32/384 reads (8%) | catalogued as COSV99763916; called by muse, mutect2
- POM121L2 | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV66277001; called by muse, mutect2, varscan2
- PSMC1 | c.744G>C p.L248F | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54320468; called by muse, mutect2
- PTCH1 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 70/958 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59469431; called by muse, mutect2
- PTGS2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443094098, COSV66570467, COSV66570993; called by muse, mutect2
- PWWP3B | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV61799702; called by muse, mutect2
- REC8 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV61018440; called by muse, mutect2
- RNF213 | c.10535C>T p.S3512F | Missense Mutation (SNP) | VAF 52/1202 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.659); catalogued as rs1324718209; called by muse, mutect2
- RRM1 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 32/614 reads (5%) | catalogued as COSV100331463; called by muse, mutect2
- RSBN1L | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 24/428 reads (6%) | catalogued as COSV100615956; called by muse, mutect2
- RTTN | c.1970C>A p.S657* | Nonsense Mutation (SNP) | VAF 32/398 reads (8%) | catalogued as rs758874457; called by muse, mutect2
- RUFY1 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV104407961; called by muse, mutect2
- RUNDC3A | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1031689162; called by muse, mutect2
- SETMAR | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.02); catalogued as COSV100740826; called by muse, mutect2, varscan2
- SIRT5 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.199); catalogued as rs771631878, COSV63080206; called by muse, mutect2, varscan2
- SLC36A1 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs376351989; called by muse, mutect2
- SLFNL1 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 12/244 reads (5%) | catalogued as COSV100263112; called by muse, mutect2
- SPATS2L | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317242560, COSV62346984; called by muse, mutect2, varscan2
- SPICE1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV55624382; called by muse, mutect2
- SPOP | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV61654631; called by muse, mutect2
- STARD9 | c.4247C>G p.S1416C | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV51913172; called by muse, mutect2
- STAT1 | c.-1G>C | Splice Region (SNP) | VAF 78/618 reads (13%) | catalogued as COSV100738938; called by muse, mutect2, varscan2
- STAT5B | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 84/686 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1449203089, COSV53180754; called by muse, varscan2
- STIL | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 31/542 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1393066121; called by muse, mutect2
- SYTL3 | c.1391G>A p.R464K (on ENST00000611299 / NM_001242394.1; = p.R396K on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51911236; called by muse, mutect2, varscan2
- TCEAL7 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 95/817 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100197073, COSV60125160; called by muse, mutect2, varscan2
- TDRD9 | c.3574C>T p.H1192Y | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as rs1274862985; called by muse, mutect2
- TNNC1 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 44/560 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.764); catalogued as rs1471808574; called by muse, mutect2
- TOPAZ1 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV59067678; called by muse, mutect2
- TRANK1 | c.3923C>G p.S1308C | Missense Mutation (SNP) | VAF 64/702 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448987598, COSV57147290; called by muse, mutect2
- TRIM7 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1303001056, COSV51249697; called by muse, mutect2, varscan2
- TRIP12 | c.2992G>C p.D998H | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772733467; called by muse, mutect2, varscan2
- TRPM3 | c.4475C>G p.S1492* (on ENST00000357533 / NM_001366142.2; = p.S1347* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 11/148 reads (7%) | catalogued as COSV62594233; called by muse, mutect2
- TSBP1 | c.776C>G p.S259C (on ENST00000617061; = p.S262C on NM_006781.5) | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66658177; called by muse, mutect2, varscan2
- TSC2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 65/792 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1442440961; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- TTN | c.99466G>T p.E33156* (on ENST00000591111; = p.E25732* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 54/472 reads (11%) | catalogued as COSV59991922, COSV60410518; called by muse, mutect2
- UBIAD1 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 50/410 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs916211527; called by muse, mutect2, varscan2
- USP31 | c.3161C>G p.S1054* | Nonsense Mutation (SNP) | VAF 16/161 reads (10%) | catalogued as COSV99565904; called by muse, mutect2, varscan2
- UVSSA | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945790378; called by muse, mutect2
- VARS2 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1255146279; called by muse, mutect2, varscan2
- VPS8 | c.3055C>G p.Q1019E (on ENST00000625842 / NM_001349294.1; = p.Q1017E on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.119); catalogued as COSV54982852; called by muse, mutect2
- ZFAT | c.1754C>G p.S585* | Nonsense Mutation (SNP) | VAF 26/418 reads (6%) | catalogued as COSV64738000; called by muse, mutect2
- ZMAT3 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 27/367 reads (7%) | catalogued as rs1363972459; called by muse, mutect2
- ZMAT4 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 26/612 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52699769; called by muse, mutect2
- ZNF236 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 49/643 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99470040; called by muse, mutect2
- ZNF417 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 58/548 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs1297849534; called by muse, mutect2, varscan2
- ZNF597 | c.1234C>G p.L412V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57083939; called by muse, mutect2
- ZNF626 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV101656935, COSV74130982; called by muse, mutect2
- ABHD12 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 100/1441 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- AC092143.1 | c.1623G>C p.E541D | Missense Mutation (SNP) | VAF 42/1160 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- AC132217.2 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 32/974 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ADAM20 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTSL1 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 32/412 reads (8%) | called by muse, mutect2
- ADGRL1 | c.2860G>C p.E954Q (on ENST00000340736 / NM_001008701.3; = p.E949Q on NM_014921.5) | Missense Mutation (SNP) | VAF 76/1084 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- AEBP1 | c.1320G>T p.R440S | Missense Mutation (SNP) | VAF 58/748 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2
- AFF4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AGTPBP1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2
- AHCTF1 | c.119G>A p.R40K (on ENST00000366508; = p.R14K on NM_015446.5) | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- AL441992.2 | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALG3 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK3 | c.8467G>T p.D2823Y | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6352C>G p.Q2118E | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD13A | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.265); called by muse, varscan2
- ANOS1 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 78/785 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP5 | c.2407C>G p.H803D | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ARHGEF2 | c.1405C>G p.L469V (on ENST00000361247 / NM_001162383.2; = p.L441V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); called by muse, mutect2
- ARHGEF2 | c.1023C>A p.F341L (on ENST00000361247 / NM_001162383.2; = p.F313L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2
- ARID5B | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ARL6IP4 | c.1050C>G p.I350M (on ENST00000315580 / NM_018694.3; = p.I331M on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/642 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATF7IP | c.2989C>T p.Q997* | Nonsense Mutation (SNP) | VAF 55/408 reads (13%) | called by muse, mutect2, varscan2
- ATM | c.8770G>C p.E2924Q | Missense Mutation (SNP) | VAF 27/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATRNL1 | c.3714C>T p.F1238= | Splice Region (SNP) | VAF 36/428 reads (8%) | called by muse, mutect2
- BRAP | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CACNA1F | c.4918G>C p.E1640Q | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.136); called by muse, mutect2
- CADPS2 | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- CAGE1 | c.448T>C p.Y150H (on ENST00000512086; = p.Y14H on NM_205864.3) | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CAMSAP1 | c.2685G>C p.Q895H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAV3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 91/847 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CC2D1A | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDC25C | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CDH12 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- CDYL2 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 31/321 reads (10%) | called by muse, mutect2
- CEMP1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
- CEP350 | c.8614G>A p.D2872N | Missense Mutation (SNP) | VAF 23/661 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFAP97D1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); called by muse, mutect2
- CLIP2 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 42/664 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNGA3 | c.1004G>A p.W335* | Nonsense Mutation (SNP) | VAF 39/336 reads (12%) | called by muse, mutect2, varscan2
- COBLL1 | c.3437C>G p.S1146C (on ENST00000392717; = p.S1108C on NM_014900.5) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL27A1 | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- COPB1 | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- CPNE6 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CRACD | c.2959G>C p.E987Q | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CRTAP | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- CTSC | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 25/808 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- CUX2 | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- DAAM1 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2
- DAB1 | c.1150C>T p.Q384* (on ENST00000371231; = p.Q351* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/437 reads (5%) | called by muse, mutect2
- DCTN1 | c.3635C>G p.S1212C | Missense Mutation (SNP) | VAF 24/671 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- DDA1 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DISP2 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 41/616 reads (7%) | called by muse, mutect2
- DNAAF5 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- DNAH2 | c.11804C>T p.P3935L | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DNAJA1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- DNAJC13 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- DSG2 | c.1571C>G p.P524R | Missense Mutation (SNP) | VAF 44/657 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- DST | c.4597C>G p.L1533V (on ENST00000361203 / NM_001374722.1; = p.L1207V on NM_015548.5) | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DYNC2H1 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- DZIP3 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- EED | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.027); called by muse, mutect2
- EFNB1 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 51/645 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.055); called by muse, mutect2
- ENOSF1 | c.316C>G p.L106V (on ENST00000340116 / NM_001354066.2; = p.L58V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ERCC6L | c.3363G>T p.K1121N | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ERP27 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 50/522 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- ETV4 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 53/575 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.899); called by muse, mutect2
- EZH2 | c.1957A>T p.R653* (on ENST00000460911 / NM_001203247.2; = p.R658* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- FAM53C | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM53C | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- FAT2 | c.12031A>G p.N4011D | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- FAT2 | c.9133C>T p.Q3045* | Nonsense Mutation (SNP) | VAF 30/254 reads (12%) | called by muse, mutect2, varscan2
- FAT2 | c.5491G>T p.E1831* | Nonsense Mutation (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- FERMT2 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FNBP1 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- FNBP1L | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- FNBP4 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRMPD2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 27/405 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FRYL | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- FSIP2 | c.15526G>A p.E5176K | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GCC2 | c.2215G>C p.D739H | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GCNT2 | c.1055G>A p.G352E (on ENST00000379597 / NM_001374747.1; = p.G350E on NM_001491.3) | Missense Mutation (SNP) | VAF 64/685 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); called by muse, mutect2
- GNE | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 50/566 reads (9%) | called by muse, mutect2
- GNS | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 44/640 reads (7%) | called by muse, mutect2
- GOLGB1 | c.1898C>A p.P633Q | Missense Mutation (SNP) | VAF 53/668 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.186); called by muse, mutect2
- GPBP1L1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- GPR15 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.053); called by muse, mutect2
- HIVEP2 | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HUWE1 | c.4674C>G p.I1558M | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- IFIT1B | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGSF5 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 42/562 reads (7%) | called by muse, mutect2
- KCNH2 | c.2817G>C p.E939D | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- KIAA1217 | c.4894G>A p.D1632N | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- KIAA2026 | c.4226C>T p.S1409L | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2
- KIF13A | c.5269G>A p.E1757K | Missense Mutation (SNP) | VAF 66/660 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); called by muse, mutect2
- KIF4A | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2
- KRT10 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 28/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- LAMA1 | c.6771C>G p.I2257M | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- LAMA1 | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2
- LAMA3 | c.5170G>A p.G1724S (on ENST00000313654 / NM_198129.4; = p.G115S on NM_000227.6) | Missense Mutation (SNP) | VAF 84/946 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- LAMTOR1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2
- LATS1 | c.2049G>C p.K683N | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2
- LATS1 | c.1863G>C p.K621N | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LEF1 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2
- LIN7C | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LOXL3 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LPIN1 | c.1692C>G p.I564M | Missense Mutation (SNP) | VAF 20/652 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- LRRC73 | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- MAMLD1 | c.1263C>G p.F421L | Missense Mutation (SNP) | VAF 130/1482 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- MAST4 | c.2626G>C p.E876Q (on ENST00000403625 / NM_001164664.2; = p.E687Q on NM_015183.3) | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCM9 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 80/605 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- MDC1 | c.4502C>G p.S1501C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MGAT4A | c.1095C>G p.H365Q | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- MKS1 | c.1302G>C p.W434C | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR10 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- MTTP | c.1245C>G p.F415L | Missense Mutation (SNP) | VAF 40/412 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.047); called by muse, mutect2
- MUC16 | c.20951C>G p.S6984C | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NADK2 | c.1025G>A p.G342E (on ENST00000381937 / NM_001085411.3; = p.G179E on NM_153013.4) | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2
- NAPG | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- NBEAL1 | c.7991C>G p.S2664* | Nonsense Mutation (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NCS1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.402); called by muse, mutect2
- NDC1 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2
- NDUFA13 | c.95-8C>G | Splice Region (SNP) | VAF 43/708 reads (6%) | called by muse, mutect2
- NEB | c.3832C>G p.L1278V | Missense Mutation (SNP) | VAF 25/672 reads (4%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.55); called by muse, mutect2
- NEUROD4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEXMIF | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- NFRKB | c.1450C>T p.Q484* (on ENST00000446488 / NM_001143835.2; = p.Q509* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- NHLRC4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 36/539 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- NLRP3 | c.1263del p.K421Nfs*81 | Frame Shift Del (DEL) | VAF 48/457 reads (11%) | called by mutect2, pindel, varscan2
- NUP155 | c.358G>A p.D120N (on ENST00000231498 / NM_153485.3; = p.D61N on NM_004298.4) | Missense Mutation (SNP) | VAF 58/800 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP210 | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NUP54 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NUTM1 | c.3113G>A p.S1038N | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- OLFM4 | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.09); called by muse, mutect2
- OR14I1 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- OR2AP1 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- OR2H2 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2, varscan2
- OR2M7 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.077); called by muse, mutect2
- OR5AN1 | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.023); called by muse, mutect2
- OR6B2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ORC1 | c.720C>T p.G240= | Splice Region (SNP) | VAF 48/700 reads (7%) | called by muse, mutect2
- PAGE4 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 40/381 reads (10%) | called by muse, mutect2, varscan2
- PAK2 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- PALLD | c.2101-1G>C p.X701_splice | Splice Site (SNP) | VAF 84/776 reads (11%) | called by muse, mutect2, varscan2
- PAXIP1 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 44/584 reads (8%) | called by muse, mutect2
- PCDH11X | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 50/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA3 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- PDZD4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 64/596 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- POLI | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPFIBP2 | c.534G>C p.M178I | Missense Mutation (SNP) | VAF 29/634 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- PPL | c.3907C>G p.Q1303E | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2
- PPL | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.265); called by muse, mutect2
- PPP3CC | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 54/547 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PPP5C | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 54/802 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- PRICKLE1 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 58/664 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT1 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PRMT1 | c.759+3G>C | Splice Region (SNP) | VAF 18/199 reads (9%) | called by muse, mutect2
- PRRC2C | c.5579C>T p.S1860L (on ENST00000367742; = p.S1858L on NM_015172.4) | Missense Mutation (SNP) | VAF 64/820 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- PTPN13 | c.4459C>G p.Q1487E (on ENST00000411767 / NM_080683.3; = p.Q1468E on NM_006264.3) | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PTPN6 | c.748-1G>A p.X250_splice | Splice Site (SNP) | VAF 103/894 reads (12%) | called by muse, mutect2, varscan2
- PTPRD | c.4888C>T p.Q1630* | Nonsense Mutation (SNP) | VAF 27/347 reads (8%) | called by muse, mutect2
- PWP1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2
- PWWP2B | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RAD54L | c.2183C>G p.S728C | Missense Mutation (SNP) | VAF 30/540 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.431); called by muse, mutect2
- RAF1 | c.1804-3C>T | Splice Region (SNP) | VAF 52/580 reads (9%) | called by muse, mutect2
- RALGAPA2 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2
- RFX1 | c.1977G>C p.E659D | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2
- RGS7 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2
- RIC1 | c.3974C>G p.S1325C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2
- RIF1 | c.1314C>G p.F438L | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- RIMS2 | c.2765C>A p.S922* (on ENST00000666250 / NM_001348490.2; = p.S730* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/381 reads (5%) | called by muse, mutect2
- RLIM | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RNF139 | c.1924C>G p.Q642E | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF146 | c.353A>G p.D118G (on ENST00000368314 / NM_001242850.2; = p.D117G on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF168 | c.651C>G p.N217K | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2
- RNF169 | c.1595C>G p.S532* | Nonsense Mutation (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- RPL26L1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- RRNAD1 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2
- RTL9 | c.3654C>G p.F1218L | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SASH1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SCN10A | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 58/673 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SCN3A | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 21/393 reads (5%) | called by muse, mutect2
- SETD2 | c.4219del p.R1407Gfs*5 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.1980G>C p.E660D | Missense Mutation (SNP) | VAF 50/531 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2
- SIRPB2 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SKAP2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2
- SLC49A4 | c.233C>G p.S78W | Missense Mutation (SNP) | VAF 65/806 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2
- SLFN14 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOD2 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 71/505 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPTB | c.6223G>C p.E2075Q | Missense Mutation (SNP) | VAF 66/900 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2
- SRCAP | c.7641G>C p.L2547F | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2
- SRCAP | c.9036G>C p.K3012N | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); called by muse, mutect2
- ST6GALNAC2 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 36/470 reads (8%) | called by muse, mutect2
- STRAP | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STRIP2 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- STUM | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); called by muse, varscan2
- SULT2B1 | c.597G>A p.M199I (on ENST00000201586 / NM_177973.2; = p.M184I on NM_004605.2) | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SUMO2 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- SYNCRIP | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 73/534 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE2 | c.4863T>A p.N1621K | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- TAS2R41 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- TBC1D1 | c.1550A>T p.K517I | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- TBC1D14 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2
- TBC1D2B | c.2593C>G p.L865V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCF19 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TDRD6 | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- TENM3 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 28/706 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TFPI | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- THRAP3 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); called by muse, mutect2
- TIGD7 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 49/559 reads (9%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.861); called by muse, mutect2
- TMEM121B | c.1491_1494del p.I498Sfs*92 | Frame Shift Del (DEL) | VAF 62/576 reads (11%) | called by mutect2, pindel
- TMEM178A | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TMEM98 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2
- TNFRSF10B | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 71/539 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- TNIK | c.2696G>C p.R899T | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2
- TRIM33 | c.3292G>A p.D1098N | Missense Mutation (SNP) | VAF 64/940 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.681); called by muse, mutect2
- TRIM73 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.02); called by muse, mutect2
- TTN | c.11249C>A p.S3750* (on ENST00000591111; = p.S3704* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 50/467 reads (11%) | called by muse, mutect2, varscan2
- TUT7 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2
- VARS2 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2
- VARS2 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- VCAN | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR61 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WIPF2 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- XPOT | c.1573-1G>C p.X525_splice | Splice Site (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- YAE1 | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2, varscan2
- YWHAZ | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 74/606 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZDHHC12 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- ZFP37 | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ZKSCAN2 | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2
- ZNF17 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2
- ZNF239 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF300 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 50/439 reads (11%) | called by muse, varscan2
- ZNF417 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ZNF527 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2
- ZNF615 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF627 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZSCAN5B | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 23/568 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- ZSWIM6 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2
- ZSWIM6 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZZZ3 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2
- ABCC5 | c.1053G>T p.T351= | Silent (SNP) | VAF 29/272 reads (11%) | called by muse, mutect2, varscan2
- AC139530.2 | c.144C>T p.L48= | Silent (SNP) | VAF 38/328 reads (12%) | catalogued as rs181881366; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1281C>T p.F427= | Silent (SNP) | VAF 33/580 reads (6%) | called by muse, mutect2
- AKR1B15 | c.390G>C p.L130= | Silent (SNP) | VAF 40/596 reads (7%) | catalogued as COSV71151535, COSV71152658; called by muse, mutect2
- AL441992.2 | c.642C>T p.I214= | Silent (SNP) | VAF 38/392 reads (10%) | catalogued as rs373732706; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2605C>T p.L869= | Silent (SNP) | VAF 28/314 reads (9%) | catalogued as COSV51849970; called by muse, mutect2
- APAF1 | c.1275C>T p.F425= (on ENST00000551964 / NM_181861.2; = p.F414= on NM_001160.3) | Silent (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- APBB1 | c.1707C>T p.V569= | Silent (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- APOB | c.10734C>T p.F3578= | Silent (SNP) | VAF 54/335 reads (16%) | catalogued as rs773361538; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.3015G>A p.L1005= | Silent (SNP) | VAF 34/760 reads (4%) | called by muse, mutect2
- ARHGAP15 | c.678G>A p.Q226= | Silent (SNP) | VAF 31/335 reads (9%) | called by muse, mutect2
- ARHGAP5 | c.3303G>A p.Q1101= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as rs558000347; called by muse, varscan2
- ATP8B3 | c.2613G>C p.R871= | Silent (SNP) | VAF 25/241 reads (10%) | called by muse, mutect2
- BMP5 | c.666C>T p.I222= | Silent (SNP) | VAF 34/406 reads (8%) | called by muse, mutect2
- C1orf159 | c.171C>G p.L57= | Silent (SNP) | VAF 63/597 reads (11%) | called by muse, mutect2, varscan2
- CA9 | c.39G>A p.L13= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- CACNA1E | c.6279C>T p.L2093= (on ENST00000367573 / NM_001205293.3; = p.L2050= on NM_000721.4) | Silent (SNP) | VAF 29/333 reads (9%) | called by muse, mutect2
- CAPN15 | c.81G>A p.E27= | Silent (SNP) | VAF 18/391 reads (5%) | called by muse, mutect2
- CARMIL3 | c.1728G>C p.L576= | Silent (SNP) | VAF 36/533 reads (7%) | called by muse, mutect2
- CASKIN1 | c.621C>T p.L207= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs1030714769; called by muse, mutect2
- CCDC102B | c.723G>A p.L241= | Silent (SNP) | VAF 60/858 reads (7%) | called by muse, mutect2
- CCDC151 | c.642G>A p.E214= | Silent (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- CCR8 | c.198G>A p.L66= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- CFAP20 | c.513C>G p.L171= | Silent (SNP) | VAF 43/506 reads (8%) | called by muse, mutect2
- CIC | c.4527G>A p.L1509= | Silent (SNP) | VAF 57/524 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2238C>T p.D746= | Silent (SNP) | VAF 52/693 reads (8%) | catalogued as rs375648820, COSV62146656; ClinVar: uncertain significance; called by muse, mutect2
- COL6A3 | c.5457G>A p.A1819= | Silent (SNP) | VAF 42/553 reads (8%) | catalogued as rs377249790, COSV99799960; called by muse, mutect2
- CTDSP1 | c.318C>T p.F106= | Silent (SNP) | VAF 46/360 reads (13%) | called by muse, mutect2, varscan2
- CTNNB1 | c.1770C>T p.I590= | Silent (SNP) | VAF 72/840 reads (9%) | called by muse, mutect2
- CYP2F1 | c.606C>T p.I202= | Silent (SNP) | VAF 38/373 reads (10%) | catalogued as COSV58527403; called by muse, mutect2, varscan2
- DEF6 | c.591G>A p.V197= | Silent (SNP) | VAF 50/593 reads (8%) | called by muse, mutect2
- DHX40 | c.1056G>A p.L352= | Silent (SNP) | VAF 22/485 reads (5%) | called by muse, mutect2
- DLGAP3 | c.2688C>G p.L896= | Silent (SNP) | VAF 30/856 reads (4%) | catalogued as COSV52392460; called by muse, mutect2
- DNAH17 | c.3246C>T p.F1082= | Silent (SNP) | VAF 27/223 reads (12%) | called by muse, mutect2, varscan2
- DPP6 | c.1905G>A p.Q635= (on ENST00000377770 / NM_001364500.2; = p.Q573= on NM_001936.5) | Silent (SNP) | VAF 26/361 reads (7%) | catalogued as COSV59628924; called by muse, mutect2
- DUSP8 | c.132C>T p.L44= | Silent (SNP) | VAF 53/458 reads (12%) | called by muse, mutect2, varscan2
- DYNLRB2 | c.267C>T p.I89= | Silent (SNP) | VAF 28/470 reads (6%) | catalogued as rs1323353674, COSV58416356; called by muse, mutect2
- EIF2B5 | c.876G>A p.G292= (on ENST00000647909; = p.G284= on NM_003907.3) | Silent (SNP) | VAF 46/547 reads (8%) | called by muse, mutect2
- EPS8L1 | c.1179C>G p.L393= (on ENST00000201647 / NM_133180.3; = p.L266= on NM_017729.3) | Silent (SNP) | VAF 38/406 reads (9%) | called by muse, mutect2
- FAM111B | c.1314C>T p.F438= | Silent (SNP) | VAF 67/565 reads (12%) | catalogued as rs762194748; called by muse, mutect2, varscan2
- FAM43A | c.459C>T p.F153= | Silent (SNP) | VAF 49/514 reads (10%) | called by muse, mutect2
- FAT1 | c.3366C>T p.F1122= | Silent (SNP) | VAF 23/425 reads (5%) | called by muse, mutect2
- FCGBP | c.5322G>A p.V1774= | Silent (SNP) | VAF 61/532 reads (11%) | called by muse, mutect2, varscan2
- FECH | c.42C>T p.A14= | Silent (SNP) | VAF 64/671 reads (10%) | catalogued as rs780466392; called by muse, mutect2
- FGB | c.736A>C p.R246= | Silent (SNP) | VAF 38/482 reads (8%) | called by muse, mutect2
- FOXF2 | c.42C>G p.R14= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- GFM1 | c.72G>A p.Q24= | Silent (SNP) | VAF 78/1080 reads (7%) | catalogued as rs766862933; called by muse, mutect2
- GOLGA3 | c.1924C>T p.L642= | Silent (SNP) | VAF 12/245 reads (5%) | called by muse, mutect2
- GPR171 | c.546C>T p.F182= | Silent (SNP) | VAF 52/498 reads (10%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1197C>T p.L399= | Silent (SNP) | VAF 30/288 reads (10%) | catalogued as rs190526971; called by muse, mutect2, varscan2
- GUCY1A1 | c.1854C>T p.V618= | Silent (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- HSD17B7 | c.729G>A p.L243= | Silent (SNP) | VAF 28/376 reads (7%) | called by muse, mutect2
- IGF2R | c.6222C>T p.V2074= | Silent (SNP) | VAF 44/273 reads (16%) | catalogued as rs779478938; called by muse, mutect2, varscan2
- ITGA2B | c.1467C>G p.V489= | Silent (SNP) | VAF 46/933 reads (5%) | called by muse, mutect2
- JMJD1C | c.2112C>T p.I704= | Silent (SNP) | VAF 27/258 reads (10%) | called by muse, mutect2, varscan2
- JUN | c.681G>A p.E227= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- KCNJ2 | c.441C>T p.F147= | Silent (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- KIF1A | c.5038C>T p.L1680= (on ENST00000320389 / NM_001379639.1; = p.L1672= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 97/695 reads (14%) | called by muse, mutect2, varscan2
- KIF1B | c.1449C>T p.I483= (on ENST00000377086 / NM_001365952.1; = p.I437= on NM_015074.3) | Silent (SNP) | VAF 76/616 reads (12%) | called by muse, mutect2, varscan2
- KLC3 | c.1401C>T p.L467= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs866260593; called by muse, mutect2
- LAMA3 | c.3390C>T p.V1130= | Silent (SNP) | VAF 111/1508 reads (7%) | catalogued as COSV58071308; called by muse, mutect2
- LRRC1 | c.873C>T p.L291= | Silent (SNP) | VAF 31/273 reads (11%) | called by muse, mutect2, varscan2
- LRRC71 | c.1365C>A p.L455= | Silent (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- LY6K | c.384C>A p.I128= | Silent (SNP) | VAF 70/465 reads (15%) | called by muse, mutect2, varscan2
- MAMDC4 | c.1812G>A p.K604= | Silent (SNP) | VAF 54/475 reads (11%) | called by muse, mutect2, varscan2
- MEGF6 | c.1881C>T p.L627= | Silent (SNP) | VAF 47/421 reads (11%) | catalogued as rs976868367; called by muse, mutect2, varscan2
- MIDEAS | c.1980C>T p.L660= | Silent (SNP) | VAF 21/411 reads (5%) | catalogued as rs1158568050, COSV54097222; called by muse, mutect2
- MUC17 | c.9513C>T p.V3171= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV60287593; called by muse, mutect2, varscan2
- MYH7 | c.4845G>A p.K1615= | Silent (SNP) | VAF 58/905 reads (6%) | called by muse, mutect2
- NAGLU | c.243G>A p.T81= | Silent (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- NEO1 | c.105G>A p.R35= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- NPAP1 | c.2016C>T p.I672= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- NSMCE3 | c.378C>T p.L126= | Silent (SNP) | VAF 37/410 reads (9%) | catalogued as COSV54292019; called by muse, mutect2
- OR1D2 | c.861C>T p.F287= | Silent (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- OR2AP1 | c.123G>C p.L41= | Silent (SNP) | VAF 44/502 reads (9%) | called by muse, mutect2
- OR5M11 | c.840G>A p.V280= | Silent (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2
- PCDHGB7 | c.1473C>A p.L491= | Silent (SNP) | VAF 29/378 reads (8%) | catalogued as COSV99531314; called by muse, mutect2
- PER1 | c.2334G>A p.L778= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57922085; called by muse, varscan2
- PEX6 | c.2079C>T p.A693= | Silent (SNP) | VAF 69/438 reads (16%) | catalogued as rs774509670; called by muse, mutect2, varscan2
- PGAM2 | c.294C>T p.L98= | Silent (SNP) | VAF 94/1076 reads (9%) | catalogued as COSV51979159; called by muse, mutect2
- PGM5 | c.1362C>T p.V454= | Silent (SNP) | VAF 25/389 reads (6%) | catalogued as COSV67168234; called by muse, mutect2
- PIDD1 | c.2556C>G p.L852= | Silent (SNP) | VAF 36/452 reads (8%) | catalogued as rs763267001; called by muse, mutect2
- PIGT | c.591C>G p.S197= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV54126835; called by muse, mutect2
- PLCB2 | c.636C>T p.L212= | Silent (SNP) | VAF 20/257 reads (8%) | called by muse, mutect2
- PLCB3 | c.2325G>A p.V775= | Silent (SNP) | VAF 21/315 reads (7%) | called by muse, mutect2
- PLCH1 | c.612C>T p.F204= (on ENST00000340059 / NM_001130960.2; = p.F216= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs1178371316; called by muse, mutect2
- PLEC | c.11700G>A p.S3900= (on ENST00000322810 / NM_201380.4; = p.S3790= on NM_000445.5) | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs373507638; called by muse, mutect2, varscan2
- PRAMEF2 | c.831C>T p.I277= | Silent (SNP) | VAF 73/505 reads (14%) | catalogued as COSV53577686; called by muse, mutect2, varscan2
- PTPN1 | c.1275C>G p.L425= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV99246246; called by muse, mutect2
- PWWP3A | c.576C>T p.V192= (on ENST00000627377; = p.V191= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 54/485 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.483C>G p.L161= | Silent (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- RET | c.6G>A p.A2= | Silent (SNP) | VAF 55/524 reads (10%) | catalogued as rs1243883489; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFX8 | c.345G>A p.R115= (on ENST00000646446; = p.R44= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 44/419 reads (11%) | catalogued as rs374167633; called by muse, mutect2, varscan2
- RYR2 | c.1893C>G p.L631= | Silent (SNP) | VAF 28/456 reads (6%) | catalogued as COSV63703214; called by muse, mutect2
- SEMA4G | c.540C>G p.L180= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- SHROOM4 | c.1272G>T p.V424= | Silent (SNP) | VAF 52/894 reads (6%) | called by muse, mutect2
- SIGLEC6 | c.288C>G p.L96= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV58432170; called by muse, mutect2
- SLC25A48 | c.897G>A p.P299= (on ENST00000650267; = p.R249H on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/464 reads (9%) | catalogued as rs1356589572; called by muse, mutect2
- SLC27A2 | c.420G>A p.A140= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV51059292; called by muse, mutect2
- SLC35G2 | c.1080C>G p.V360= | Silent (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- SLC43A1 | c.441C>T p.I147= | Silent (SNP) | VAF 32/746 reads (4%) | called by muse, mutect2
- SLC66A3 | c.84G>A p.V28= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- SLC6A14 | c.1068C>T p.L356= | Silent (SNP) | VAF 78/657 reads (12%) | catalogued as COSV64148698; called by muse, mutect2, varscan2
- ST14 | c.1162C>T p.L388= | Silent (SNP) | VAF 57/434 reads (13%) | called by muse, mutect2, varscan2
- TEX47 | c.549C>G p.L183= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- TNFSF9 | c.123C>T p.L41= | Silent (SNP) | VAF 58/638 reads (9%) | catalogued as rs1201505923, COSV55538496; called by muse, mutect2
- TSHR | c.327G>C p.R109= | Silent (SNP) | VAF 53/804 reads (7%) | catalogued as COSV53328394; called by muse, mutect2
- TTBK1 | c.3018C>T p.P1006= | Silent (SNP) | VAF 44/372 reads (12%) | called by muse, mutect2, varscan2
- UBN1 | c.3396G>A p.R1132= | Silent (SNP) | VAF 24/542 reads (4%) | called by muse, mutect2
- UROD | c.168C>T p.F56= | Silent (SNP) | VAF 43/798 reads (5%) | called by muse, mutect2
- VARS2 | c.1338G>C p.L446= | Silent (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- WARS1 | c.1371G>A p.V457= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as COSV100690059; called by muse, mutect2
- WDR38 | c.339C>T p.F113= | Silent (SNP) | VAF 48/722 reads (7%) | called by muse, mutect2
- WDR48 | c.546C>T p.I182= | Silent (SNP) | VAF 50/598 reads (8%) | called by muse, mutect2
- WDR7 | c.2682C>T p.I894= | Silent (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- ZFP28 | c.756C>T p.F252= | Silent (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- ZNF135 | c.1509C>T p.F503= (on ENST00000313434 / NM_001289401.2; = p.F515= on NM_003436.4) | Silent (SNP) | VAF 44/747 reads (6%) | called by muse, mutect2
- ZNF239 | c.885G>A p.K295= | Silent (SNP) | VAF 28/313 reads (9%) | catalogued as rs370581500; called by muse, mutect2
- ZNF534 | c.1044C>T p.F348= (on ENST00000332323 / NM_001143939.3; = p.F335= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/343 reads (10%) | catalogued as rs942136569; called by muse, mutect2
- ZNF624 | c.2115C>T p.F705= | Silent (SNP) | VAF 27/430 reads (6%) | called by muse, mutect2
- ZNF696 | c.954G>A p.E318= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- ZNF783 | c.540C>G p.V180= | Silent (SNP) | VAF 46/578 reads (8%) | called by muse, mutect2
- ZNF787 | c.921C>T p.L307= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as rs1397015731; called by muse, mutect2, varscan2
- ZNF829 | c.1053C>G p.L351= | Silent (SNP) | VAF 46/450 reads (10%) | called by muse, mutect2
- ZNF862 | c.3468C>G p.L1156= | Silent (SNP) | VAF 31/331 reads (9%) | called by muse, mutect2
- ABCC8 | c.2391-45C>G | Intron (SNP) | VAF 19/398 reads (5%) | called by muse, mutect2
- ACKR1 | chr1:159204874 C>G | 5'Flank (SNP) | VAF 38/326 reads (12%) | called by muse, mutect2, varscan2
- ADD1 | c.1413+49C>G | Intron (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- AL109984.1 | n.186+1438C>G | Intron (SNP) | VAF 22/179 reads (12%) | catalogued as rs910415829, COSV100801802; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501898 del G | 5'Flank (DEL) | VAF 53/499 reads (11%) | called by mutect2, pindel
- ASS1 | c.*44C>T | 3'UTR (SNP) | VAF 44/414 reads (11%) | catalogued as rs866764088; called by muse, mutect2, varscan2
- ATL2 | c.119-10581C>A | Intron (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- BCL2L15 | c.*16C>T | 3'UTR (SNP) | VAF 19/470 reads (4%) | called by muse, mutect2
- BRD2 | c.-1G>C | 5'UTR (SNP) | VAF 94/928 reads (10%) | catalogued as COSV66373193; called by muse, varscan2
- BTNL10 | n.592C>G | RNA (SNP) | VAF 42/704 reads (6%) | called by muse, mutect2
- C5orf22 | c.1060-2736C>T | Intron (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- C8orf58 | c.*81C>T | 3'UTR (SNP) | VAF 41/385 reads (11%) | called by muse, mutect2, varscan2
- CAMK2A | c.1033+91C>A | Intron (SNP) | VAF 48/671 reads (7%) | called by muse, mutect2
- CCM2 | c.31-10512C>G | Intron (SNP) | VAF 63/967 reads (7%) | called by muse, mutect2
- CDKN3 | c.416+1946C>G | Intron (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- CHRNA10 | c.-17C>G | 5'UTR (SNP) | VAF 50/439 reads (11%) | called by muse, mutect2, varscan2
- COL11A2 | c.-5C>G | 5'UTR (SNP) | VAF 118/1144 reads (10%) | called by muse, mutect2
- COL4A1 | c.615+54G>A | Intron (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- COL4A1 | c.552+14G>A | Intron (SNP) | VAF 42/910 reads (5%) | called by muse, mutect2
- COQ5 | c.*205C>G | 3'UTR (SNP) | VAF 14/279 reads (5%) | catalogued as rs1207775065; called by muse, mutect2
- CSPP1 | c.534+44C>T | Intron (SNP) | VAF 40/349 reads (11%) | catalogued as rs1277282232; called by muse, mutect2, varscan2
- CYP4F12 | c.-2+108C>A | Intron (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- DCP2 | c.-131C>G | 5'UTR (SNP) | VAF 40/400 reads (10%) | catalogued as rs756125676; called by muse, mutect2
- DPP4 | c.-41C>G | 5'UTR (SNP) | VAF 32/185 reads (17%) | catalogued as rs769901680; called by muse, mutect2, varscan2
- DPP9 | c.2245-236C>T | Intron (SNP) | VAF 15/123 reads (12%) | catalogued as rs1214287601; called by muse, mutect2, varscan2
- DUSP12 | c.-12C>G | 5'UTR (SNP) | VAF 40/496 reads (8%) | called by muse, mutect2
- ETV5 | c.-17G>C | 5'UTR (SNP) | VAF 52/697 reads (7%) | catalogued as rs762959301, COSV100112249; called by muse, mutect2
- FIBP | c.411+44C>A | Intron (SNP) | VAF 35/746 reads (5%) | called by muse, mutect2
- FLVCR1 | c.*48C>T | 3'UTR (SNP) | VAF 21/405 reads (5%) | called by muse, mutect2
- GTPBP3 | chr19:17335040 C>G | 5'Flank (SNP) | VAF 27/545 reads (5%) | called by muse, mutect2
- GVINP1 | n.3966G>C | RNA (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- HELLS | c.436-11C>G | Intron (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- HGSNAT | c.1013-1640G>A | Intron (SNP) | VAF 8/64 reads (13%) | catalogued as rs368341838; called by muse, varscan2
- HMG20B | c.*239G>A | 3'UTR (SNP) | VAF 37/636 reads (6%) | catalogued as rs930461614; called by muse, mutect2
- HNRNPA3P1 | n.166G>T | RNA (SNP) | VAF 47/412 reads (11%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.-11C>T | 5'UTR (SNP) | VAF 48/492 reads (10%) | called by muse, mutect2, varscan2
- IGSF9B | c.64+4615C>T | Intron (SNP) | VAF 29/337 reads (9%) | called by muse, mutect2
- IL18BP | chr11:71999195 G>C | 5'Flank (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- KANSL1 | c.-89-24183C>G | Intron (SNP) | VAF 40/846 reads (5%) | called by muse, mutect2
- KCTD7 | c.*1266C>G | 3'UTR (SNP) | VAF 29/224 reads (13%) | called by muse, mutect2, varscan2
- KDM5C | c.2244-22C>T | Intron (SNP) | VAF 82/832 reads (10%) | catalogued as rs1276293861; called by muse, mutect2
- KIF18B | c.*7G>C | 3'UTR (SNP) | VAF 44/692 reads (6%) | called by muse, mutect2
- LIG1 | c.2004+48G>T | Intron (SNP) | VAF 24/242 reads (10%) | catalogued as rs781377073; called by muse, mutect2, varscan2
- LIMS1 | c.-5+32964C>T | Intron (SNP) | VAF 33/614 reads (5%) | called by muse, mutect2
- MAP1LC3A | c.-87G>C | 5'UTR (SNP) | VAF 13/65 reads (20%) | catalogued as rs1418370166, COSV54164902; called by muse, mutect2
- MAP2K2 | c.705+31C>G | Intron (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- MCOLN1 | c.-69G>A | 5'UTR (SNP) | VAF 29/357 reads (8%) | called by muse, mutect2
- MYH16 | n.3298G>A | RNA (SNP) | VAF 26/360 reads (7%) | catalogued as rs888487413; called by muse, mutect2
- NDUFB10 | chr16:1965344 G>A | 3'Flank (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- NEO1 | c.-32C>A | 5'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- NUP153 | c.-5C>T | 5'UTR (SNP) | VAF 61/532 reads (11%) | catalogued as rs1032845148, COSV50462610; called by muse, mutect2, varscan2
- NUP210P1 | n.241C>T | RNA (SNP) | VAF 33/284 reads (12%) | called by muse, mutect2, varscan2
- OGG1 | c.138-44G>A | Intron (SNP) | VAF 42/413 reads (10%) | called by muse, mutect2
- OR2L1P | n.609C>G | RNA (SNP) | VAF 25/258 reads (10%) | catalogued as rs377532419; called by muse, mutect2
- PAWR | c.684-8007G>A | Intron (SNP) | VAF 20/462 reads (4%) | called by muse, mutect2
- PGRMC1 | c.-26G>A | 5'UTR (SNP) | VAF 95/717 reads (13%) | catalogued as COSV99483428; called by muse, mutect2, varscan2
- PKNOX2 | c.-130+23712G>A | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53548359; called by muse, varscan2
- PLEKHA2 | c.*780G>A | 3'UTR (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- PNKP | c.-1G>A | 5'UTR (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- PTBP1 | c.892+323C>G | Intron (SNP) | VAF 48/502 reads (10%) | called by muse, mutect2
- RAMP2 | chr17:42760902 C>G | 5'Flank (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- RNF213 | c.11055-49G>C | Intron (SNP) | VAF 23/164 reads (14%) | catalogued as rs1315348911; called by muse, mutect2, varscan2
- RPS6 | c.138+10G>A | Intron (SNP) | VAF 29/486 reads (6%) | called by muse, mutect2
- S1PR3 | chr9:88991072 C>T | 5'Flank (SNP) | VAF 102/1091 reads (9%) | called by muse, mutect2
- SHLD2P1 | n.2373G>C | RNA (SNP) | VAF 14/107 reads (13%) | called by mutect2, varscan2
- SLC25A13 | c.*710G>A | 3'UTR (SNP) | VAF 75/935 reads (8%) | called by muse, mutect2
- SNORD109A | n.61G>C | RNA (SNP) | VAF 13/273 reads (5%) | called by muse, mutect2
- SP100 | c.-42G>A | 5'UTR (SNP) | VAF 57/493 reads (12%) | called by muse, mutect2, varscan2
- SQLE | c.-825G>T | 5'UTR (SNP) | VAF 39/346 reads (11%) | catalogued as rs1244082301; called by muse, mutect2, varscan2
- STARD3 | c.429+44G>A | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as COSV60421375; called by muse, mutect2, varscan2
- TMEM135 | c.*6113G>C | 3'UTR (SNP) | VAF 34/490 reads (7%) | called by muse, mutect2
- TOX4 | c.-1G>C | 5'UTR (SNP) | VAF 64/944 reads (7%) | called by muse, mutect2
- TRIM25 | c.*812C>T | 3'UTR (SNP) | VAF 30/506 reads (6%) | called by muse, mutect2
- TRPA1 | c.1530-45C>T | Intron (SNP) | VAF 34/251 reads (14%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2912+33237C>T | Intron (SNP) | VAF 18/380 reads (5%) | called by muse, mutect2
- TTC6 | chr14:37790823 C>T | 5'Flank (SNP) | VAF 29/369 reads (8%) | called by muse, mutect2
- UBTFL2 | n.441G>C | RNA (SNP) | VAF 29/864 reads (3%) | called by muse, mutect2
- WT1 | chr11:32439536 C>G | 5'Flank (SNP) | VAF 44/922 reads (5%) | called by muse, mutect2
- Y_RNA | chr7:75511056 C>G | 3'Flank (SNP) | VAF 64/754 reads (8%) | called by muse, mutect2
- ZNF721 | chr4:435812 C>G | 3'Flank (SNP) | VAF 16/347 reads (5%) | called by muse, mutect2
